Somatic mutation profile of tumor specimen TCGA-AO-A0JE-01A (aliquot TCGA-AO-A0JE-01A-11W-A071-09) from TCGA case TCGA-AO-A0JE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.4 years (19,516 days).
Specimen TCGA-AO-A0JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee6b9698-deff-4b66-8b6f-7a34fbf4b02d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JE-10A (Blood Derived Normal), aliquot TCGA-AO-A0JE-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d1d8316-1cbc-4fda-8516-a6958a67e91e

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Nonsense Mutation 5, Intron 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STAG2 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 22/356 reads (6%) | hotspot (GDC flag); catalogued as COSV54350685, COSV54365974; called by muse, mutect2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6V0E1 | c.10C>G p.H4D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV54185777; called by muse, mutect2, varscan2
- BLM | c.3381G>T p.Q1127H | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV61926616; called by muse, mutect2, varscan2
- BRCC3 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.238); catalogued as rs374320484, COSV100341650; called by muse, mutect2
- BTN1A1 | c.1332C>G p.I444M | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55069166; called by muse, mutect2, varscan2
- CFAP206 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.364); catalogued as COSV51536512; called by muse, mutect2, varscan2
- CIT | c.4067G>A p.R1356H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774914678, COSV55863025, COSV99949497; called by muse, mutect2, varscan2
- DNAH5 | c.4736C>T p.S1579L | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs184151103, COSV54226096; called by muse, mutect2, varscan2
- DSE | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59066792; called by muse, mutect2, varscan2
- EMSY | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58264898, COSV58265028; called by muse, mutect2, varscan2
- FCER1A | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs751747623, COSV63668182; called by muse, mutect2, varscan2
- HERC1 | c.14342G>A p.R4781Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101496607; called by muse, mutect2
- IRF9 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV60703834; called by mutect2, varscan2
- KMT2C | c.3358G>T p.E1120* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV51487946; called by muse, mutect2, varscan2
- LRP2 | c.7921A>G p.N2641D | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV55569109; called by muse, mutect2, varscan2
- LYST | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773113090, COSV67712241; called by muse, mutect2, varscan2
- MIB1 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55092901; called by muse, mutect2, varscan2
- MYT1L | c.2555G>C p.R852T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV101221039, COSV67720367; called by muse, mutect2, varscan2
- NT5C1B | c.796G>A p.E266K (on ENST00000359846 / NM_001199086.2; = p.E206K on NM_033253.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as rs781054410, COSV58394503; called by muse, mutect2, varscan2
- OR2G6 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58575577; called by muse, mutect2, varscan2
- OR4D10 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 43/186 reads (23%) | catalogued as rs774314809, COSV101596994, COSV73259977; called by muse, mutect2, varscan2
- PEX19 | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV63619974; called by muse, mutect2, varscan2
- PGLYRP3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs769955259, COSV51952272; called by muse, mutect2, varscan2
- PPP2R1A | c.1752T>G p.T584= | Splice Region (SNP) | VAF 72/156 reads (46%) | catalogued as COSV59047544; called by muse, mutect2, varscan2
- RO60 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100814393; called by muse, mutect2
- SNAP25 | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV54774922; called by muse, mutect2, varscan2
- TIGD2 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV100392369; called by muse, mutect2
- TREML1 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV58295520; called by muse, mutect2, varscan2
- TTN | c.50467A>G p.K16823E (on ENST00000591111; = p.K9399E on NM_003319.4) | Missense Mutation (SNP) | VAF 45/182 reads (25%) | PolyPhen probably damaging (0.994); catalogued as COSV60278972; called by muse, mutect2, varscan2
- UNC79 | c.3177G>A p.M1059I (on ENST00000393151 / NM_001346218.2; = p.M882I on NM_020818.5) | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56405544; called by muse, mutect2, varscan2
- WFDC5 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100332185, COSV57217520; called by muse, mutect2, varscan2
- ZMAT1 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100858826, COSV100858941; called by muse, mutect2
- ZNF572 | c.985C>G p.Q329E | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV60001699, COSV60002229; called by muse, mutect2, varscan2
- ZNF587 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 69/606 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as rs755988325, COSV57150422; called by muse, mutect2, varscan2
- ZNF620 | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV58820823; called by muse, mutect2, varscan2
- DOP1B | c.3606C>T p.L1202= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV67694859; called by muse, mutect2, varscan2
- IGHV1-58 | c.315G>A p.L105= | Silent (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- MAGI1 | c.3126C>G p.S1042= (on ENST00000402939 / NM_001033057.2; = p.S1071= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV58337382, COSV58340337; called by muse, mutect2, varscan2
- MORC4 | c.1188C>A p.L396= | Silent (SNP) | VAF 70/293 reads (24%) | catalogued as COSV55245795; called by muse, mutect2, varscan2
- PLXDC1 | c.1302C>A p.V434= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100195423; called by muse, mutect2
- SLC6A4 | c.369C>T p.I123= | Silent (SNP) | VAF 34/181 reads (19%) | catalogued as COSV55569063; called by muse, mutect2, varscan2
- SQLE | c.987G>C p.P329= | Silent (SNP) | VAF 55/227 reads (24%) | catalogued as COSV56282212; called by muse, mutect2, varscan2
- TRIM5 | c.1356C>T p.F452= | Silent (SNP) | VAF 60/277 reads (22%) | catalogued as COSV59901904; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823542 G>A | 5'Flank (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2
- ARMC5 | c.1864+270C>T | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as rs377587666; called by muse, mutect2
